Somatic mutation profile of tumor specimen TCGA-21-5784-01A (aliquot TCGA-21-5784-01A-01D-1632-08) from TCGA case TCGA-21-5784, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 80.4 years (29,362 days).
Specimen TCGA-21-5784-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40781511-bcf6-42e4-a68d-91968f3e9ddf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-5784-10A (Blood Derived Normal), aliquot TCGA-21-5784-10A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e687fb07-5f3c-4ed9-b5cc-dc6bcd123cd6

The open-access MAF lists 199 somatic variants for this specimen: 154 protein-altering or splice-affecting, 43 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 43, Nonsense Mutation 8, Splice Site 7, Frame Shift Ins 2, Intron 1, Translation Start Site 1, In Frame Del 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNC | c.4021C>T p.R1341* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as rs1562998062, COSV57965369; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.1204C>A p.H402N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61260159, COSV61282370; called by muse, mutect2, varscan2
- ADGRG4 | c.8036A>T p.N2679I | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV99795573; called by muse, mutect2
- AKAP4 | c.1472C>A p.T491N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62075682; called by muse, mutect2
- ALG5 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV53507676; called by muse, mutect2, varscan2
- AMBN | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV59825672; called by muse, mutect2, varscan2
- ANKS1B | c.3476A>T p.Y1159F (on ENST00000547776 / NM_152788.4; = p.Y325F on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV59125599; called by muse, mutect2
- AP3M2 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.951); catalogued as COSV51530924; called by muse, mutect2
- ASTN1 | c.3569G>T p.R1190L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752299973, COSV62508302; called by muse, mutect2, varscan2
- ATP11C | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59575749; called by muse, mutect2
- ATP2B4 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV58184772; called by muse, mutect2, varscan2
- ATR | c.3542G>T p.G1181V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV63393449; called by muse, mutect2
- ATRX | c.3190G>A p.A1064T | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV64884787; called by muse, mutect2
- BAZ1A | c.4124C>T p.P1375L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1388472438, COSV62412336; called by muse, mutect2
- C18orf54 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV55619732; called by muse, mutect2, varscan2
- CD109 | c.3712G>A p.V1238I | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV54658024; called by muse, mutect2, varscan2
- CD1B | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV63805318; called by muse, mutect2, varscan2
- CDH12 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66453491; called by muse, mutect2, varscan2
- CNGB3 | c.620C>A p.P207Q | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV60699477; called by muse, mutect2, varscan2
- CNTRL | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53046468, COSV53054293; called by muse, mutect2, varscan2
- COL12A1 | c.5282T>A p.V1761E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59409655; called by muse, mutect2, varscan2
- COL22A1 | c.4844G>T p.S1615I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV57363636; called by muse, mutect2, varscan2
- COL22A1 | c.2319A>T p.R773S | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57363644; called by muse, mutect2
- COL4A6 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV57880302; called by muse, mutect2
- COL4A6 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV57880321; called by muse, mutect2
- COPA | c.2941G>T p.G981C | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.839); catalogued as COSV54110319; called by muse, mutect2
- COX4I1 | c.485A>T p.Y162F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV53666647; called by muse, mutect2, varscan2
- CPS1 | c.1864G>C p.V622L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.822); catalogued as CM114328, COSV51826352, COSV99244026; called by muse, mutect2, varscan2
- CRB1 | c.1879C>A p.L627M | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV66329063, COSV66334457; called by muse, mutect2
- CSF2RA | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.264); catalogued as COSV62627072; called by muse, mutect2
- CSMD2 | c.9362C>A p.P3121H | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53969800; called by muse, mutect2
- CSMD3 | c.7423C>G p.P2475A (on ENST00000297405 / NM_001363185.1; = p.P2371A on NM_052900.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52319964, COSV52337154; called by muse, mutect2
- CSNK1A1L | c.978A>T p.Q326H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.758); catalogued as COSV65790365; called by muse, mutect2, varscan2
- CWH43 | c.1682A>G p.Q561R | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1278017095, COSV56944624; called by muse, mutect2, varscan2
- CXorf21 | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV66763407; called by muse, mutect2, varscan2
- DAOA | c.358A>T p.K120* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV61603742; called by mutect2, varscan2
- DCBLD2 | c.2099C>A p.T700N | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV54585903; called by muse, mutect2, varscan2
- DCC | c.1419-2A>T p.X473_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59140538; called by muse, mutect2, varscan2
- DNAH9 | c.2959A>G p.N987D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52379757; called by muse, mutect2, varscan2
- DSG4 | c.2792C>A p.P931H | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV57398490; called by muse, mutect2, varscan2
- ENPEP | c.2792C>T p.T931I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV54458376; called by muse, mutect2, varscan2
- ERCC6L | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1250808056; called by muse, mutect2
- EXPH5 | c.2263G>T p.G755W | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV56209143, COSV99761615; called by muse, mutect2, varscan2
- FAM47A | c.1114G>T p.G372W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV60497497; called by muse, mutect2, varscan2
- FCRL2 | c.916T>A p.S306T | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1294540835, COSV63835356; called by muse, mutect2, varscan2
- FCRL5 | c.1357G>T p.G453C | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62521002; called by muse, mutect2
- FLG2 | c.2319C>A p.H773Q | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV101166237, COSV66174138; called by muse, mutect2, varscan2
- FSTL5 | c.345C>A p.H115Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60234640; called by muse, mutect2, varscan2
- GAD2 | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs765976449, COSV52169958; called by muse, mutect2
- GLUD2 | c.1205C>A p.A402D | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60153399; called by muse, mutect2
- GRIA4 | c.2543A>T p.K848M | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56922541; called by muse, mutect2
- GUCY2C | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as rs1163839028, COSV53796413; called by muse, mutect2
- H2AC12 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/89 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.019); catalogued as rs756890049, COSV63617774; called by muse, mutect2, varscan2
- H3-3B | c.79A>G p.R27G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV54667134; called by muse, mutect2
- HEATR5B | c.4252G>C p.E1418Q | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51859761; called by muse, mutect2
- HERC2 | c.8246G>C p.R2749T | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99874008; called by muse, mutect2
- IGSF1 | c.2919G>C p.L973F | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63840819; called by muse, mutect2
- IL9R | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV54902503; called by muse, mutect2, varscan2
- ITGAE | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs761465211, COSV53988675; called by muse, mutect2, varscan2
- JADE3 | c.2452C>A p.H818N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54470814; called by muse, mutect2
- KCNJ1 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764078087, CM994544, COSV60661933; called by muse, mutect2, varscan2
- KCNJ4 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 76/460 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57858276, COSV57859033; called by muse, mutect2, varscan2
- KDSR | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV58508407; called by muse, mutect2, varscan2
- KIAA0319 | c.2758C>A p.H920N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65502274; called by muse, mutect2, varscan2
- KIF21A | c.2225A>T p.H742L (on ENST00000361418 / NM_001378440.1; = p.H729L on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV62778839; called by muse, mutect2, varscan2
- KIF4B | c.2302C>T p.L768F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV70531852; called by muse, mutect2
- KLHL38 | c.1019T>A p.M340K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as rs1431433849, COSV58089474; called by muse, mutect2, varscan2
- LAMA2 | c.5518G>A p.D1840N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs759350875, COSV70338367; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAS1L | c.1653G>T p.K551N | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV56709249; called by muse, mutect2, varscan2
- LINGO2 | c.881C>A p.S294Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58065143; called by muse, mutect2, varscan2
- LLGL1 | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV57501225; called by muse, mutect2, varscan2
- LPIN1 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV56771738; called by muse, mutect2, varscan2
- LRRC8C | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV65001968; called by muse, mutect2
- MAGEA6 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61449455; called by muse, mutect2
- MAGEC1 | c.2592G>T p.L864F | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.065); catalogued as COSV53582518; called by muse, mutect2
- MBD5 | c.760A>T p.N254Y | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV68699144; called by muse, mutect2
- NDST4 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs761206860, COSV52139806, COSV99998239; called by muse, mutect2, varscan2
- NEB | c.7569G>T p.K2523N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV51464963; called by muse, mutect2
- NPVF | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs747743397, COSV56060223; called by muse, varscan2
- NPVF | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.941); catalogued as COSV56061651; called by muse, varscan2
- NT5DC3 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV67323144; called by muse, mutect2
- OPA1 | c.718C>G p.Q240E (on ENST00000361510 / NM_130837.3; = p.Q204E on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.258); catalogued as rs751085689, COSV100655332; called by mutect2, varscan2
- OR1L1 | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.435); catalogued as COSV58936926; called by muse, mutect2
- OR2M2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62899563; called by muse, mutect2, varscan2
- OR4M1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 16/227 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs770476111, COSV60063486; called by muse, mutect2
- OR4M1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV60063890; called by muse, mutect2
- OR5D18 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV61738871; called by muse, mutect2, varscan2
- PCDHB16 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs781973278, COSV53372255; called by muse, mutect2
- PKHD1 | c.6998G>T p.G2333V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV61897009; called by muse, mutect2, varscan2
- PLIN5 | c.448G>T p.A150S | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV67851165; called by muse, mutect2
- PLOD3 | c.880-1G>C p.X294_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | catalogued as COSV56186142, COSV99777735; called by muse, mutect2
- PLXNA3 | c.5100G>T p.Q1700H | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63755979; called by muse, mutect2
- PNLIPRP3 | c.1111G>C p.G371R | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65049887; called by muse, mutect2, varscan2
- POLA1 | c.2329-1G>C p.X777_splice | Splice Site (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100985315, COSV66891330; called by muse, mutect2, varscan2
- PPEF1 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62995454, COSV62996953; called by muse, mutect2
- PPP1R26 | c.2932G>T p.G978C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63357566; called by muse, mutect2, varscan2
- PPP4R2 | c.740G>C p.R247T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55598403; called by muse, mutect2, varscan2
- PROS1 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62399813; called by muse, mutect2
- PXK | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV57095072; called by muse, mutect2
- PYHIN1 | c.468A>T p.K156N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV63724321; called by muse, mutect2, varscan2
- PYHIN1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV63724334; called by muse, mutect2, varscan2
- R3HDM1 | c.1723C>T p.L575F | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.58); catalogued as COSV51533720; called by muse, mutect2, varscan2
- RNF13 | c.984A>T p.E328D | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.197); catalogued as COSV53525120; called by muse, mutect2
- ROS1 | c.1534A>T p.T512S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63862412; called by muse, mutect2, varscan2
- RUNX1T1 | c.865C>A p.L289M (on ENST00000265814 / NM_001198628.1; = p.L262M on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.535); catalogued as COSV56164978; called by muse, mutect2
- SCN1A | c.3337G>A p.V1113M (on ENST00000303395 / NM_001202435.3; = p.V1102M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs1331336011, COSV57690675; called by muse, mutect2
- SCN4A | c.1921G>T p.G641C | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71129448; called by muse, mutect2, varscan2
- SERPINA4 | c.1146C>A p.S382R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.166); catalogued as COSV54069389; called by muse, mutect2, varscan2
- SESTD1 | c.582-1G>T p.X194_splice | Splice Site (SNP) | VAF 5/57 reads (9%) | catalogued as rs1229977795, COSV58933064; called by muse, mutect2
- SGCZ | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66015721, COSV66047918; called by muse, mutect2, varscan2
- SH2D2A | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63885609; called by muse, mutect2
- SHTN1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53388519; called by muse, mutect2
- SIGLEC1 | c.2417A>G p.D806G | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52474334; called by muse, mutect2
- SKOR1 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58250482; called by muse, mutect2
- SLC8A1 | c.1038A>G p.I346M | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs760339904, COSV60498187; called by muse, mutect2
- SMG6 | c.485G>T p.R162L | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as COSV53977634; called by muse, mutect2, varscan2
- SORCS1 | c.2164G>T p.V722F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV53910230, COSV99545308; called by muse, mutect2, varscan2
- SPATA31E1 | c.3424G>T p.D1142Y | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.366); catalogued as COSV57795881; called by muse, mutect2
- SPHKAP | c.1206T>A p.D402E | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.514); catalogued as COSV60896319; called by muse, mutect2
- SPTA1 | c.2732C>G p.A911G | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196026753, COSV63760668; called by muse, mutect2, varscan2
- SPTA1 | c.419_420insT p.W140Cfs*13 | Frame Shift Ins (INS) | VAF 23/101 reads (23%) | catalogued as COSV100934996; called by mutect2, pindel, varscan2
- TAF1L | c.572C>G p.A191G | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.53); catalogued as COSV54271146; called by muse, mutect2, varscan2
- TCF25 | c.1744G>T p.G582W | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54533626; called by muse, mutect2, varscan2
- TCF25 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV54533639; called by muse, mutect2, varscan2
- TENM1 | c.7735G>C p.G2579R | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV64445471; called by muse, mutect2
- TENM1 | c.5131C>A p.Q1711K | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV64445481; called by muse, mutect2
- TEX15 | c.4061T>A p.L1354* (on ENST00000256246; = p.L1737* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 23/111 reads (21%) | catalogued as COSV56355174; called by muse, mutect2, varscan2
- THSD7A | c.3334G>T p.V1112L | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.304); catalogued as COSV70273858; called by muse, mutect2, varscan2
- TLR4 | c.655C>A p.Q219K (on ENST00000355622 / NM_138554.5; = p.Q179K on NM_003266.4) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100790658, COSV62924436; called by muse, mutect2
- TMEM132D | c.1873C>A p.Q625K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV67162883; called by muse, mutect2
- TNN | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53437224; called by mutect2, varscan2
- TPR | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV66599066; called by muse, mutect2
- TRAF1 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65869535; called by muse, mutect2, varscan2
- TTN | c.27589G>A p.E9197K (on ENST00000591111; = p.E8270K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | PolyPhen probably damaging (0.994); catalogued as COSV60387540; called by muse, mutect2, varscan2
- TTN | c.19483A>T p.K6495* (on ENST00000591111; = p.K5568* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV60387554; called by muse, mutect2
- UCHL5 | c.434+2T>A p.X145_splice | Splice Site (SNP) | VAF 9/44 reads (20%) | catalogued as COSV66487253; called by muse, mutect2, varscan2
- VCAN | c.2081T>C p.M694T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs781418554, COSV54118034; called by muse, mutect2, varscan2
- WAS | c.107T>A p.F36Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as CD951883, COSV64997824; called by muse, mutect2
- WDR44 | c.2384+1G>T p.X795_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54170015; called by muse, mutect2, varscan2
- ZDHHC9 | c.1023C>A p.S341R | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV64097534; called by muse, mutect2, varscan2
- ZFHX4 | c.2965A>G p.K989E | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs990934665, COSV51499698; called by muse, mutect2, varscan2
- ZFP37 | c.1258C>G p.L420V | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as COSV65288972; called by muse, mutect2
- ZFP64 | c.1531A>T p.I511F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53804408; called by muse, mutect2
- ZNF217 | c.254T>C p.L85S | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201521105, COSV56600858; called by muse, mutect2, varscan2
- ZNF521 | c.3817C>A p.Q1273K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV100831341, COSV64132512; called by muse, mutect2, varscan2
- ZNF608 | c.3239A>G p.Y1080C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60441896; called by muse, mutect2, varscan2
- ZNF763 | c.713G>T p.S238I (on ENST00000358987 / NM_001367172.2; = p.S241I on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.721); catalogued as COSV59689252; called by muse, mutect2, varscan2
- ZNF804B | c.380G>C p.C127S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV60858960; called by muse, mutect2, varscan2
- AMER2 | c.301del p.V101* | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- GSDMC | c.1083+1del p.X361_splice | Splice Site (DEL) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- IGKV1-8 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PTEN | c.395_409del p.G132_C136del | In Frame Del (DEL) | VAF 8/96 reads (8%) | called by mutect2, pindel
- PTPRC | c.931dup p.C311Lfs*5 | Frame Shift Ins (INS) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- ACSL5 | c.1947C>T p.S649= (on ENST00000354273; = p.S705= on NM_016234.3) | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV61133881; called by muse, mutect2, varscan2
- ANKRD17 | c.7773A>G p.A2591= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV58228700; called by muse, mutect2, varscan2
- ANKRD17 | c.2754A>C p.G918= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV58228708; called by muse, mutect2, varscan2
- ATP10A | c.2037G>T p.S679= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1185531572, COSV100791304, COSV63525849; called by muse, mutect2
- ATP11C | c.507C>A p.T169= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV59575714; called by muse, mutect2
- BCOR | c.1149C>T p.F383= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV60703078, COSV60720106; called by muse, mutect2, varscan2
- BRINP3 | c.2283G>C p.T761= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV66523337, COSV66543118; called by muse, mutect2, varscan2
- C6 | c.801A>G p.Q267= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs935750215, COSV54720302; called by muse, mutect2, varscan2
- CDH8 | c.1629G>A p.P543= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs980808256, COSV54856948; called by muse, mutect2
- CHAT | c.1863C>T p.D621= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV60334410; called by muse, mutect2, varscan2
- DSG2 | c.3169C>T p.L1057= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV55203601; called by muse, mutect2
- DSG4 | c.2793C>G p.P931= | Silent (SNP) | VAF 29/166 reads (17%) | catalogued as COSV57391616; called by muse, mutect2, varscan2
- DYNC1I1 | c.477G>T p.L159= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV61472572; called by muse, mutect2, varscan2
- EXTL1 | c.579C>A p.G193= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV65338486; called by muse, mutect2, varscan2
- FLNA | c.6486C>A p.L2162= (on ENST00000369850 / NM_001110556.2; = p.L2154= on NM_001456.3) | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV100774335, COSV61052873; called by muse, mutect2
- FOXN1 | c.258C>T p.P86= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1390351192, COSV56884410; ClinVar: likely benign; called by muse, mutect2, varscan2
- GINS4 | c.303G>A p.E101= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs141057295, COSV52531649; called by muse, mutect2
- H2BC18 | c.222C>T p.I74= | Silent (SNP) | VAF 11/186 reads (6%) | catalogued as rs782575950, COSV100516145, COSV58944587; called by muse, mutect2
- IGKV3D-20 | c.234C>A p.G78= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- KCNC4 | c.465G>A p.E155= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV63926807; called by muse, mutect2
- MAGEB6 | c.984T>A p.A328= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as COSV66873264; called by muse, mutect2
- MAP2 | c.3714G>A p.E1238= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs779240553, COSV52310360, COSV99561491; called by mutect2, varscan2
- MTBP | c.1461G>A p.L487= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV59966876; called by muse, mutect2, varscan2
- NISCH | c.4119C>G p.L1373= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58743837; called by muse, mutect2, varscan2
- NUP98 | c.3198A>G p.Q1066= (on ENST00000359171 / NM_001365126.1; = p.Q1049= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1454031161, COSV61439510; called by muse, mutect2
- OR5M11 | c.591C>A p.A197= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- OR8D2 | c.747C>A p.G249= | Silent (SNP) | VAF 7/115 reads (6%) | catalogued as COSV62489174; called by muse, mutect2
- PCDH10 | c.2664A>T p.L888= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1425356772, COSV52105394; called by muse, mutect2, varscan2
- PEG3 | c.1263G>A p.E421= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as COSV55636244, COSV55643835; called by muse, mutect2, varscan2
- PRKD1 | c.2337C>T p.G779= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs1313944586, COSV59580309; called by muse, mutect2
- RASGRF1 | c.858C>T p.V286= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV69183799; called by muse, mutect2
- RBFA | c.150G>C p.S50= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as rs1347536822, COSV51533154; called by muse, mutect2
- SEL1L2 | c.1056G>A p.P352= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs773756757, COSV53149775, COSV53158088; called by muse, mutect2
- SEMG2 | c.138G>A p.Q46= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV65648054; called by muse, mutect2
- SLC24A5 | c.1464A>T p.G488= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV51054577; called by muse, mutect2, varscan2
- SMARCA1 | c.639G>T p.G213= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as COSV64414101; called by muse, mutect2
- TRANK1 | c.8256G>A p.E2752= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV57166124; called by muse, mutect2, varscan2
- TRGV5 | c.111T>C p.A37= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- VCPIP1 | c.1248T>C p.A416= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as COSV60050336; called by muse, mutect2, varscan2
- WDR72 | c.2010G>A p.V670= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV64752648; called by muse, mutect2
- WLS | c.54T>C p.G18= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV52047759; called by muse, mutect2, varscan2
- YY2 | c.789G>A p.K263= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as COSV63410567, COSV63412659; called by muse, mutect2
- ZBTB10 | c.1800A>G p.S600= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV66948673; called by muse, mutect2
- AMACR | c.739+1180_739+1183del | Intron (DEL) | VAF 3/38 reads (8%) | called by mutect2, pindel
- MIR545 | n.38A>G | RNA (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
